Somatic mutation profile of tumor specimen TCGA-EK-A2GZ-01A (aliquot TCGA-EK-A2GZ-01A-11D-A17W-09) from TCGA case TCGA-EK-A2GZ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 64.6 years (23,599 days).
Specimen TCGA-EK-A2GZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14fa2b48-bdc6-4cdd-abd9-6781caa49554.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2GZ-10A (Blood Derived Normal), aliquot TCGA-EK-A2GZ-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9386ed2-176a-41b8-a1c3-7782c8044e68

The open-access MAF lists 85 somatic variants for this specimen: 61 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 22, Frame Shift Del 4, Nonsense Mutation 3, Intron 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPRIN2 | c.298A>C p.T100P | Missense Mutation (SNP) | VAF 6/13 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs7090312; called by muse, mutect2, varscan2
- ADCK5 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as COSV58232084; called by muse, mutect2, varscan2
- ALPK1 | c.3466G>A p.E1156K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV51581468; called by muse, mutect2, varscan2
- ATG2A | c.4563C>A p.F1521L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV65965775; called by mutect2, varscan2
- CCDC150 | c.1654G>T p.E552* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as COSV55871526, COSV55873578; called by muse, varscan2
- CDH12 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV101201879; called by muse, mutect2
- CDIN1 | c.559C>T p.R187C (on ENST00000437989; = p.R89C on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57709552, COSV57713470; called by muse, mutect2
- CYP11A1 | c.610C>A p.R204S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV51430535, COSV51434240; called by muse, mutect2, varscan2
- DAPK1 | c.3389G>A p.R1130H | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1411904981, COSV63783899; called by muse, mutect2, varscan2
- DEF6 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as rs1277970439, COSV57353016; called by muse, mutect2
- DHRSX | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as COSV58129885; called by muse, mutect2, varscan2
- FSIP2 | c.20053G>A p.D6685N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV58077801; called by muse, mutect2, varscan2
- GHR | c.1738G>A p.G580R | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.956); catalogued as COSV50105898; called by muse, mutect2, varscan2
- HRH4 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs915066300, COSV56927161; called by muse, mutect2, varscan2
- HSD3B2 | c.216C>G p.C72W | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101027436; called by muse, mutect2
- ITPK1 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs750906842, COSV50893830; called by muse, mutect2, varscan2
- KCNT1 | c.1126G>A p.A376T (on ENST00000488444; = p.A395T on NM_020822.3) | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV53695209; called by muse, mutect2
- KCNU1 | c.2626C>T p.Q876* | Nonsense Mutation (SNP) | VAF 32/89 reads (36%) | catalogued as COSV67752892; called by muse, mutect2, varscan2
- KIFC1 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1268176276, COSV65737290; called by muse, mutect2, varscan2
- LARP4B | c.1225C>T p.R409* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV60219797; called by muse, mutect2, varscan2
- MCM2 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as rs200231306, COSV54031921; called by muse, mutect2, varscan2
- MMEL1 | c.1393A>G p.K465E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV56518218; called by muse, mutect2, varscan2
- MYH2 | c.2438G>T p.R813I | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV55431145, COSV55438869; called by muse, mutect2, varscan2
- NAV2 | c.2857G>C p.V953L (on ENST00000396087 / NM_001244963.2; = p.V930L on NM_145117.5) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs752368978, COSV60656261; called by muse, mutect2, varscan2
- NBAS | c.5074C>T p.R1692C | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs779626422, COSV55711612; called by muse, mutect2
- NDN | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1457193891, COSV59358294; called by muse, mutect2, varscan2
- NLGN3 | c.2251G>A p.G751R (on ENST00000358741 / NM_181303.2; = p.G731R on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.07); catalogued as rs17857400, COSV62441538; called by muse, mutect2, varscan2
- NUP210L | c.3623C>T p.A1208V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV55141104; called by muse, mutect2, varscan2
- NWD1 | c.3739G>A p.E1247K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs781315143, COSV60337371; called by muse, mutect2, varscan2
- OR7C1 | c.26C>A p.A9D | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV50182837; called by muse, mutect2, varscan2
- P2RX2 | c.830C>T p.S277L (on ENST00000343948 / NM_170683.4; = p.S205L on NM_012226.5) | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs1033799448, COSV57673710, COSV57673937; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.766G>A p.E256K (on ENST00000259318 / NM_001136562.3; = p.E487K on NM_007203.5) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.588); catalogued as rs751156000, COSV52172928; called by muse, mutect2, varscan2
- PCYOX1L | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as rs780048660, COSV51002061; called by muse, mutect2, varscan2
- PDK2 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV50303232; called by muse, mutect2, varscan2
- PDXDC1 | c.1364C>T p.T455M | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs770182198, COSV100362975; called by muse, mutect2
- PGBD5 | c.574G>A p.D192N (on ENST00000525115; = p.D261N on NM_001258311.2) | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV58410493; called by muse, mutect2, varscan2
- PRR15 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV60501693; called by muse, mutect2, varscan2
- RUNDC3A | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs563233289, COSV56636952; called by muse, mutect2, varscan2
- SERPINI2 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs753865354, COSV52984166; called by muse, mutect2, varscan2
- SMCHD1 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.239); catalogued as COSV55251228, COSV55266219; called by muse, mutect2, varscan2
- SPON1 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.207); catalogued as rs782473008, COSV59957362; called by muse, mutect2, varscan2
- TBC1D26 | c.161A>T p.E54V | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV68608479; called by muse, mutect2, varscan2
- THAP7 | c.572G>A p.C191Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV53144974; called by muse, mutect2, varscan2
- TJP2 | c.2652G>T p.W884C | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99600802; called by muse, mutect2
- TNN | c.895G>C p.G299R | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV99511385; called by muse, mutect2
- TOX | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs751683918, COSV63842137; called by muse, mutect2, varscan2
- TPR | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66599266; called by muse, mutect2, varscan2
- UNC13C | c.5304T>A p.T1768= | Splice Region (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99513548; called by muse, mutect2, varscan2
- UTP4 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs145040987; called by muse, mutect2, varscan2
- ZCWPW2 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.07); catalogued as rs370104321; called by muse, mutect2, varscan2
- ZIM2 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs896127224, COSV55624163; called by muse, mutect2, varscan2
- ZNF292 | c.1174A>G p.S392G | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV60535315; called by muse, mutect2, varscan2
- ZNF436 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as rs773419541, COSV58357966; called by muse, mutect2, varscan2
- ZNF70 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs1188191693, COSV59532040; called by muse, mutect2, varscan2
- AXIN2 | c.1870C>A p.L624M | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.377); called by muse, mutect2
- EED | c.880del p.I294Sfs*22 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | called by mutect2, pindel, varscan2
- EFEMP2 | c.594C>A p.N198K | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); called by muse, mutect2
- GAPDHS | c.980del p.Y327Sfs*8 | Frame Shift Del (DEL) | VAF 21/97 reads (22%) | called by mutect2, pindel, varscan2
- KIAA0100 | c.4208_4227del p.D1403Gfs*18 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel
- TMPRSS15 | c.1150C>T p.H384Y | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF667 | c.351del p.A118Lfs*14 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel, varscan2
- AFDN | c.3924G>A p.Q1308= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV60036829, COSV60060178; called by muse, mutect2, varscan2
- AQP10 | c.832C>T p.L278= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV59244575; called by muse, mutect2, varscan2
- BCAR1 | c.2280C>T p.N760= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as rs371417209, COSV50778626; called by muse, mutect2, varscan2
- CERK | c.696G>C p.R232= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV53450003; called by mutect2, varscan2
- CNOT8 | c.669G>A p.R223= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as rs374069510; called by muse, varscan2
- CPA1 | c.552C>T p.V184= | Silent (SNP) | VAF 35/107 reads (33%) | catalogued as COSV50568089; called by muse, mutect2, varscan2
- CPSF1 | c.3558C>T p.I1186= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as rs781881999, COSV58232088; called by muse, mutect2, varscan2
- EEF1A2 | c.942C>T p.N314= | Silent (SNP) | VAF 62/156 reads (40%) | catalogued as rs758126231, COSV53204654; called by muse, mutect2, varscan2
- ENO1 | c.726C>T p.I242= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as rs926942765, COSV52303655; called by muse, mutect2, varscan2
- ERF | c.1646G>A p.*549= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV55894910; called by muse, mutect2, varscan2
- ICA1 | c.99G>A p.T33= | Silent (SNP) | VAF 44/161 reads (27%) | catalogued as rs745708769, COSV55575787; called by muse, mutect2, varscan2
- KMT5A | c.483C>A p.I161= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV57862162; called by muse, mutect2, varscan2
- PCDHA11 | c.1338C>T p.D446= | Silent (SNP) | VAF 68/216 reads (31%) | catalogued as COSV56476032; called by muse, mutect2, varscan2
- PRKD1 | c.1476C>T p.F492= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs1050229277, COSV59558823; called by muse, mutect2, varscan2
- RAB11B | c.222C>T p.R74= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs564081021, COSV60085208; called by muse, mutect2, varscan2
- RSBN1L | c.519C>T p.L173= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs1416837335, COSV58506187; called by muse, mutect2, varscan2
- SLC6A4 | c.576G>A p.T192= | Silent (SNP) | VAF 16/184 reads (9%) | catalogued as rs927827964, COSV99911245, COSV99911259; called by muse, mutect2
- TBCD | c.408C>T p.V136= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs1297337878, COSV62797439; called by muse, mutect2, varscan2
- WDR81 | c.4683C>T p.S1561= (on ENST00000409644 / NM_001163809.2; = p.S510= on NM_152348.4) | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs1171865761, COSV58478248; called by muse, mutect2, varscan2
- ZBTB3 | c.1293C>T p.F431= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV67360816, COSV67360821; called by muse, mutect2, varscan2
- ZNF101 | c.873C>T p.L291= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100543497; called by muse, mutect2, varscan2
- ZNF536 | c.360C>T p.I120= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV62817887; called by muse, mutect2, varscan2
- C16orf91 | c.*48C>A | 3'UTR (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100113764, COSV59949560, COSV59949818; called by muse, mutect2, varscan2
- PNLIPRP1 | c.331-395G>C | Intron (SNP) | VAF 9/44 reads (20%) | catalogued as COSV62610666; called by muse, mutect2, varscan2
